CCDI case PBCIBZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f8319f25-2c16-40e8-ab70-7a97fc55f2e8

Demographics
Sex at birth: female.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.5 years (1,277 days).

Biospecimens (3 samples)
- Sample 0DSPLO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSPLW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSPM0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
